Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3CC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3CC-06A (Metastatic).

DIAGNOSIS

Patient ID -

(A) RIGHT AXILLARY CONTENTS:

METASTATIC MELANOMA IN ONE OF NINETEEN LYMPH NODES (1/19).

SIZE IS 40 X 30 MM.

TUMOR IS SUBCAPSULAR AND INTRAPARENCHYMAL.

EXTRANODAL EXTENSION IS PRESENT.

(B) LEFT BACK, SKIN EXCISION:

Follicular cyst, infundibular type.

Entire report and diagnosis completed by

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph nodes, axilla

077-3

W 10/3/11

GROSS DESCRIPTION

(A) RIGHT AXILLARY CONTENTS, STERILE FOR MVAX PROTOCOL - A non-oriented irregular fragment of adipose tissue (15.0 x 10.0 x 3.0 cm). The specimen is serially sectioned and 19 lymph nodes are identified, ranging from (0.3 x 0.2 x 0.2 to 4.0 x 3.0 x 2.5 cm). The cut surface of the largest lymph node is firm and dark-brown.

SECTION CODE: A1, three lymph nodes; A2, four lymph nodes; A3, three lymph nodes; A4, one lymph node bisected; A5, one lymph node bisected; A6, two lymph nodes; A7, two lymph nodes; A8, one lymph node; A9-A14, one lymph node serially sectioned; A15-A18, largest lymph node serially sectioned.

(B) WIDE LOCAL EXCISION, LEFT BACK, SHORT STITCH = SUPERIOR, LONG STITCH = LATERAL - An ellipse of light tan skin and subcutaneous tissue (7.0 x 3.5 x 1.8 cm) with a centrally located irregular roughened lightly pigmented area (1.9 x 1.6 cm). The superior stitch is designated as 12 o'clock.

INK CODE: Blue - 9, 12, 3 o'clock; orange - 3, 6, 9 o'clock.

A centrally located smooth walled cyst (2.0 cm in diameter) filled with yellow cheesy material is noted. The specimen is serially sectioned from the 3 o'clock to 9 o'clock tip.

SECTION CODE: B1, 3 o'clock tip; B2-B14, one complete cross section from 3-9 o'clock in each cassette; B15, 9 o'clock tip.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

T-C4710, T-02450, M-87206, M-33410

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

. These tests have not been

-----END OF REPORT-----

	Yes	No
Criteria		

Source: NCI Genomic Data Commons file 93efdf46-3ebe-43dd-95b0-f7434f5b6d44 (TCGA-D3-A3CC.76C039FE-FD6A-4919-BCF3-86CFEFBDEBB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).